Somatic mutation profile of tumor specimen TARGET-30-PASGAP-01A (aliquot TARGET-30-PASGAP-01A-01D) from TARGET case TARGET-30-PASGAP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.6 years (1,330 days).
Specimen TARGET-30-PASGAP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4f88b48-cd63-4ee5-9254-722494c66022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASGAP-10A (Blood Derived Normal), aliquot TARGET-30-PASGAP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9205e855-1720-4010-8d73-ccbf0e9f0985

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN7 | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63040313; called by muse, mutect2, varscan2
- DSCAML1 | c.293C>A p.S98Y (on ENST00000321322; = p.S38Y on NM_020693.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58403699; called by muse, mutect2, varscan2
- FLG | c.11017G>A p.D3673N | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.525); catalogued as rs773092738, COSV64240872; called by mutect2, varscan2
- MSH4 | c.1449G>C p.R483S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV54213485; called by muse, mutect2, varscan2
- MTCL1 | c.2206G>T p.G736W (on ENST00000306329 / NM_001378206.1; = p.G376W on NM_015210.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60412402; called by muse, mutect2, varscan2
- MYOT | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | catalogued as rs371052066; called by muse, mutect2, varscan2
- PDE4DIP | c.6952+1G>T p.X2318_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as rs370659192, COSV57684171; called by muse, mutect2
- PIK3CA | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV56005994; called by muse, mutect2, varscan2
- POLDIP3 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1430667214, COSV52810406; called by muse, mutect2, varscan2
- PPBP | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV56020300; called by muse, mutect2, varscan2
- SEC61A2 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs911799216, COSV53655477; called by muse, mutect2, varscan2
- SLC30A4 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV56007671; called by muse, mutect2, varscan2
- TMEM81 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.123); catalogued as rs146591308; called by muse, mutect2, varscan2
- ZC3H12C | c.1404C>A p.N468K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.217); catalogued as COSV53713201; called by muse, mutect2, varscan2
- OR6C2 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); called by muse, mutect2
- CCL3L3 | c.54C>T p.C18= | Silent (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- DENND2B | c.1164C>A p.P388= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as COSV58208134; called by muse, mutect2, varscan2
- MAP3K21 | c.2817C>G p.V939= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV64042794; called by muse, mutect2, varscan2
- OR2T1 | c.150A>C p.T50= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV63542992; called by muse, mutect2, varscan2
- TINAG | c.906A>T p.V302= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV52515893; called by muse, mutect2, varscan2
- UBC | c.1905G>A p.K635= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as rs1071746, COSV60061580; called by muse, varscan2
